Somatic mutation profile of tumor specimen HCM-CSHL-0740-C18-06A (aliquot HCM-CSHL-0740-C18-06A-11D-A83U-36) from HCMI case HCM-CSHL-0740-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.8 years (24,398 days).
Specimen HCM-CSHL-0740-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12abd418-99da-4758-94c5-5fcae80e4390.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0740-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0740-C18-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a811d5d2-1750-42b8-b6d6-9e227c72e663

The open-access MAF lists 241 somatic variants for this specimen: 192 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 168, Silent 43, Nonsense Mutation 14, Intron 6, Frame Shift Ins 3, Splice Region 2, Splice Site 2, In Frame Del 1, Translation Start Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 124/482 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 257/452 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 64/375 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs149808995, COSV104400112; called by muse, mutect2, varscan2
- ADGRV1 | c.13850G>A p.G4617E | Missense Mutation (SNP) | VAF 30/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs182984071; called by muse, mutect2, varscan2
- AMER1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 298/924 reads (32%) | catalogued as COSV57653855, COSV57662082; called by muse, mutect2, varscan2
- ANKRD30A | c.608A>C p.K203T (on ENST00000611781; = p.K147T on NM_052997.2) | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as COSV64604232, COSV64607964; called by muse, mutect2
- APC | c.4561G>T p.E1521* | Nonsense Mutation (SNP) | VAF 213/703 reads (30%) | catalogued as COSV57322883; called by muse, mutect2, varscan2
- ARHGAP15 | c.1178C>A p.S393Y | Missense Mutation (SNP) | VAF 146/276 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV54488028, COSV99711194; called by muse, mutect2, varscan2
- ASTN1 | c.3130G>T p.E1044* | Nonsense Mutation (SNP) | VAF 69/496 reads (14%) | catalogued as COSV62492108, COSV62507875; called by muse, mutect2, varscan2
- ATP6V0D1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 108/751 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52098584; called by muse, mutect2, varscan2
- B4GALNT1 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 113/664 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV57542808; called by muse, mutect2, varscan2
- BMPR2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 198/407 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs200339485; called by muse, mutect2, varscan2
- C17orf97 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 224/606 reads (37%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs782081322; called by muse, varscan2
- CAMKV | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 280/574 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs573710169, COSV56556591, COSV99616148; called by muse, mutect2, varscan2
- CD5L | c.57G>A p.A19= | Splice Region (SNP) | VAF 95/309 reads (31%) | catalogued as rs143489369; called by muse, mutect2, varscan2
- CLSTN2 | c.1646C>A p.S549Y | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV71721529; called by muse, mutect2, varscan2
- CNP | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 363/685 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782788519; called by muse, mutect2, varscan2
- COL4A5 | c.4228C>T p.R1410C | Missense Mutation (SNP) | VAF 135/453 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as rs104886270, CM960393, COSV60377043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTR9 | c.3229C>T p.R1077* | Nonsense Mutation (SNP) | VAF 192/518 reads (37%) | catalogued as COSV63728658; called by muse, varscan2
- CTSG | c.67G>A p.G23R | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1566552319, COSV53535683; called by muse, mutect2
- DCTD | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs766885547, COSV100830103; called by muse, mutect2, varscan2
- DENND3 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164686761, COSV52802220; called by muse, mutect2, varscan2
- DLG2 | c.211C>T p.P71S | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as rs1226023254; called by muse, mutect2, varscan2
- DPEP1 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 89/546 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV55360633; called by muse, mutect2, varscan2
- ENAM | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 45/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs757420971; called by muse, mutect2, varscan2
- EPB41L1 | c.2246C>T p.T749M | Missense Mutation (SNP) | VAF 61/501 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as rs200279989; called by muse, mutect2, varscan2
- ETV3 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 165/558 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1042519523; called by muse, mutect2, varscan2
- EXOC3L1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 162/809 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1205484225, COSV99333968; called by muse, mutect2, varscan2
- FFAR2 | c.775G>A p.V259M | Missense Mutation (SNP) | VAF 234/529 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs145373857; called by muse, mutect2, varscan2
- FGFR2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 134/439 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs998662110, COSV60643939; called by muse, mutect2, varscan2
- FPR2 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 87/440 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1203326424; called by muse, mutect2, varscan2
- FREM2 | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 117/1009 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- GABRA5 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs576861235, COSV59475453; called by muse, mutect2, varscan2
- GPR119 | c.641C>A p.S214Y | Missense Mutation (SNP) | VAF 168/863 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV52275394; called by muse, mutect2, varscan2
- GRIN2A | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 89/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746978701, COSV58019618; called by muse, mutect2, varscan2
- GRTP1 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 672/938 reads (72%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs776947918; called by muse, mutect2, varscan2
- GSX1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 715/1004 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57233287; called by muse, mutect2, varscan2
- HCAR1 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 113/664 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs147267914; called by muse, mutect2, varscan2
- HS1BP3 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 122/769 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs758703154; called by muse, mutect2, varscan2
- HUNK | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 265/576 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs772115970, COSV54226478; called by muse, mutect2, varscan2
- HYDIN | c.3713C>A p.S1238* | Nonsense Mutation (SNP) | VAF 73/442 reads (17%) | catalogued as COSV66833996; called by muse, mutect2, varscan2
- KCNT1 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 71/345 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV53702828; called by muse, mutect2, varscan2
- KCNT2 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 41/329 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV99656335; called by muse, mutect2, varscan2
- KRTAP4-11 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 495/1361 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs756399704, COSV101194914; called by muse, mutect2, varscan2
- LINGO1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 320/612 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.111); catalogued as rs756041181; called by muse, mutect2, varscan2
- MAGEC1 | c.2901A>C p.E967D | Missense Mutation (SNP) | VAF 68/522 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV53568177; called by muse, mutect2, varscan2
- MAP3K15 | c.2252A>C p.K751T | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.646); catalogued as COSV58827337; called by muse, mutect2, varscan2
- MUC16 | c.13378T>G p.L4460V | Missense Mutation (SNP) | VAF 130/537 reads (24%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.135); catalogued as COSV67495851; called by muse, mutect2, varscan2
- NAALAD2 | c.755A>G p.N252S | Missense Mutation (SNP) | VAF 66/336 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs950711606; called by muse, mutect2, varscan2
- NAV2 | c.3551G>A p.R1184Q (on ENST00000396087 / NM_001244963.2; = p.R1161Q on NM_145117.5) | Missense Mutation (SNP) | VAF 96/626 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.394); catalogued as rs752367379, COSV60664981, COSV99051762; called by muse, mutect2, varscan2
- NELFB | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 33/493 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs369149566; called by muse, mutect2
- NKX2-6 | c.670G>A p.G224R | Missense Mutation (SNP) | VAF 180/1050 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); catalogued as rs991694173; called by muse, mutect2, varscan2
- NLRP13 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 85/390 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193094359, COSV100738237, COSV100738685; called by muse, mutect2, varscan2
- NOX5 | c.1511T>A p.I504N | Missense Mutation (SNP) | VAF 132/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1255084042; called by muse, mutect2, varscan2
- OR1I1 | c.928G>A p.V310I | Missense Mutation (SNP) | VAF 166/355 reads (47%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs147609807; called by muse, mutect2, varscan2
- OR7G3 | c.724G>T p.G242W | Missense Mutation (SNP) | VAF 99/404 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59640707; called by muse, mutect2, varscan2
- OR8K3 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as rs755503510; called by muse, mutect2, varscan2
- PCDH11X | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015996; called by muse, mutect2, varscan2
- PCDHA3 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 210/754 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65371842; called by muse, mutect2, varscan2
- PCDHB3 | c.2096C>T p.S699L | Missense Mutation (SNP) | VAF 308/1053 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as rs1554272666, COSV50629424; called by muse, mutect2, varscan2
- PCDHGA9 | c.1942G>C p.D648H | Missense Mutation (SNP) | VAF 125/768 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs772084097; called by muse, mutect2, varscan2
- PCLO | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 65/550 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.399); catalogued as COSV100438594, COSV61629629; called by muse, mutect2, varscan2
- PIH1D1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 194/427 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.073); catalogued as rs773060882; called by muse, mutect2, varscan2
- POU3F4 | c.27C>A p.Y9* | Nonsense Mutation (SNP) | VAF 104/498 reads (21%) | catalogued as COSV64540595; called by muse, mutect2, varscan2
- POU4F1 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 72/888 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.689); catalogued as rs1159888057; called by muse, mutect2
- POU4F2 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 155/866 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs1414203136; called by muse, varscan2
- PROCR | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 117/819 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs757907256; called by muse, mutect2, varscan2
- PTPRN2 | c.1554_1556+1del p.X518_splice | Splice Site (DEL) | VAF 122/410 reads (30%) | catalogued as rs745584393; called by mutect2, pindel, varscan2
- PVRIG | c.357A>C p.E119D | Missense Mutation (SNP) | VAF 133/809 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as rs1369370812; called by muse, mutect2, varscan2
- RIC8B | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 44/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773118905, COSV62695853; called by muse, mutect2, varscan2
- RNPEP | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 187/614 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767769940; called by muse, mutect2, varscan2
- RYR3 | c.3125G>A p.R1042H | Missense Mutation (SNP) | VAF 163/369 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781225171, COSV101215514; called by muse, mutect2, varscan2
- SAMD9 | c.3188G>T p.G1063V | Missense Mutation (SNP) | VAF 85/497 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV66075340; called by muse, mutect2, varscan2
- SCN7A | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV101313213; called by muse, mutect2, varscan2
- SEL1L | c.2333G>A p.R778Q | Missense Mutation (SNP) | VAF 88/521 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.278); catalogued as rs376067391, COSV60921719; called by muse, mutect2, varscan2
- SERPINB3 | c.1138A>G p.S380G | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs778873893; called by muse, mutect2, varscan2
- SETMAR | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 141/334 reads (42%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.115); catalogued as rs553781514; called by muse, mutect2, varscan2
- SIAH3 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 598/869 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1193045104; called by muse, mutect2, varscan2
- SLC6A19 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 155/491 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs771770693, COSV58670995; called by muse, mutect2, varscan2
- STS | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 68/452 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs1214783952; called by muse, mutect2, varscan2
- SYNE1 | c.10288G>A p.G3430R (on ENST00000367255 / NM_182961.4; = p.G3437R on NM_033071.3) | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs1047722501, COSV54952483; called by muse, mutect2, varscan2
- TBRG1 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 139/360 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV52516541; called by muse, mutect2, varscan2
- TECTA | c.4276G>A p.G1426S | Missense Mutation (SNP) | VAF 95/465 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143250687; called by muse, mutect2, varscan2
- TENM1 | c.6772G>A p.A2258T | Missense Mutation (SNP) | VAF 66/832 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as rs377058853, COSV64431401; called by muse, mutect2
- TEX26 | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as COSV66840096; called by muse, mutect2
- TKTL2 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 95/536 reads (18%) | catalogued as rs569128837; called by muse, mutect2, varscan2
- TMEM127 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 197/676 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.127); catalogued as rs746831347, COSV51497970; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TMEM132C | c.2852A>C p.K951T | Missense Mutation (SNP) | VAF 135/681 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59421132; called by muse, mutect2, varscan2
- TRIM58 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 466/973 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760428256; called by muse, mutect2, varscan2
- TRIM71 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 196/405 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV101070415, COSV67472660; called by muse, mutect2, varscan2
- TTN | c.27368G>A p.G9123D (on ENST00000591111; = p.G8196D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/688 reads (31%) | PolyPhen probably damaging (0.959); catalogued as COSV100614414; called by muse, mutect2, varscan2
- TXNDC11 | c.2749G>A p.E917K (on ENST00000356957 / NM_001303447.2; = p.E890K on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/700 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1178197263; called by muse, mutect2, varscan2
- UBE3B | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 75/422 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs200362048, COSV99783896; called by muse, mutect2, varscan2
- UBXN11 | c.736G>A p.D246N (on ENST00000374221 / NM_183008.2; = p.D213N on NM_145345.2) | Missense Mutation (SNP) | VAF 93/495 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as rs1437631876; called by muse, mutect2, varscan2
- USP19 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 236/519 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs745611822; called by muse, mutect2, varscan2
- XKR4 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 138/774 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as COSV59318070; called by muse, mutect2, varscan2
- ZNF648 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 322/666 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs910726353, COSV60572288; called by muse, mutect2, varscan2
- ABCA13 | c.12650G>A p.R4217H | Missense Mutation (SNP) | VAF 362/1012 reads (36%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ADAM33 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 76/637 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.14071G>C p.D4691H | Missense Mutation (SNP) | VAF 75/421 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- AKR1B15 | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 46/357 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.1720A>T p.K574* | Nonsense Mutation (SNP) | VAF 12/324 reads (4%) | called by muse, mutect2
- ANKRD18A | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 24/944 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.265); called by muse, mutect2
- ANKS1A | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 394/1036 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.11); called by muse, varscan2
- ANKS1B | c.1946A>C p.K649T | Missense Mutation (SNP) | VAF 67/455 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.2936dup p.M979Ifs*6 | Frame Shift Ins (INS) | VAF 134/551 reads (24%) | called by mutect2, pindel, varscan2
- AVPR1A | c.335A>G p.D112G | Missense Mutation (SNP) | VAF 222/680 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- BICRA | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 168/760 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BPTF | c.4818C>G p.S1606R | Missense Mutation (SNP) | VAF 91/459 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C12orf40 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- C19orf67 | c.965C>A p.P322H | Missense Mutation (SNP) | VAF 133/636 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CATIP | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CCDC144A | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 202/627 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CD163 | c.1835G>T p.W612L | Missense Mutation (SNP) | VAF 128/798 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFH | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 129/402 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRB1 | c.3893T>G p.I1298S | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2
- CRMP1 | c.1461G>A p.K487= | Splice Region (SNP) | VAF 41/317 reads (13%) | called by muse, mutect2, varscan2
- CSMD1 | c.7117T>G p.F2373V (on ENST00000520002; = p.F2372V on NM_033225.6) | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- CTC1 | c.2842G>A p.V948I | Missense Mutation (SNP) | VAF 26/668 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CTSV | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 62/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFB114 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DGKZ | c.707A>T p.Q236L | Missense Mutation (SNP) | VAF 123/710 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH1 | c.4692C>G p.Y1564* | Nonsense Mutation (SNP) | VAF 140/301 reads (47%) | called by muse, mutect2, varscan2
- EHMT1 | c.1282A>C p.K428Q | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2
- ELP6 | c.727T>C p.F243L | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA2 | c.2915T>G p.V972G | Missense Mutation (SNP) | VAF 97/363 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, varscan2
- FAM111B | c.1089A>C p.Q363H | Missense Mutation (SNP) | VAF 63/411 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM135B | c.3082G>C p.V1028L | Missense Mutation (SNP) | VAF 21/583 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2
- FAM47B | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 178/723 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- FASTKD2 | c.639T>G p.F213L | Missense Mutation (SNP) | VAF 14/494 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- FREM3 | c.369A>T p.Q123H | Missense Mutation (SNP) | VAF 195/1037 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- GK | c.1623dup p.I542Yfs*4 (on ENST00000427190 / NM_001205019.2; = p.I536Yfs*4 on NM_001128127.2) | Frame Shift Ins (INS) | VAF 68/362 reads (19%) | called by mutect2, pindel, varscan2
- GLT8D2 | c.942G>A p.W314* | Nonsense Mutation (SNP) | VAF 77/419 reads (18%) | called by muse, mutect2, varscan2
- GPR15 | c.266G>C p.W89S | Missense Mutation (SNP) | VAF 22/435 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HIF1A | c.1033A>G p.I345V | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HYDIN | c.3712T>A p.S1238T | Missense Mutation (SNP) | VAF 74/441 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGSF9B | c.2507A>C p.K836T | Missense Mutation (SNP) | VAF 123/631 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IL10RA | c.1308A>C p.E436D | Missense Mutation (SNP) | VAF 120/667 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KCNC1 | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 126/677 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5C | c.3512A>C p.K1171T | Missense Mutation (SNP) | VAF 160/787 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- KHDC1 | c.434T>G p.V145G (on ENST00000370384 / NM_001251874.2; = p.V72G on NM_030568.5) | Missense Mutation (SNP) | VAF 90/510 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KIF19 | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 138/709 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- LAMA2 | c.5249T>A p.L1750H | Missense Mutation (SNP) | VAF 124/276 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LMTK2 | c.3433A>C p.S1145R | Missense Mutation (SNP) | VAF 109/780 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRIT3 | c.1036C>A p.L346I | Missense Mutation (SNP) | VAF 94/546 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MAD1L1 | c.1957T>G p.S653A | Missense Mutation (SNP) | VAF 114/787 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEA10 | c.410A>C p.K137T | Missense Mutation (SNP) | VAF 118/712 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MAP7D3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 177/828 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MDN1 | c.16663C>T p.R5555* | Nonsense Mutation (SNP) | VAF 122/353 reads (35%) | called by muse, mutect2, varscan2
- MEI4 | c.479T>G p.L160* | Nonsense Mutation (SNP) | VAF 16/452 reads (4%) | called by muse, mutect2
- MFSD3 | c.761A>T p.N254I | Missense Mutation (SNP) | VAF 235/822 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MICAL1 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 161/455 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MSN | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 195/998 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUC16 | c.22638G>T p.E7546D | Missense Mutation (SNP) | VAF 221/416 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NHLH2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 296/643 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOP2 | c.1083C>A p.Y361* (on ENST00000322166 / NM_001258308.2; = p.Y357* on NM_006170.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 186/611 reads (30%) | called by muse, mutect2, varscan2
- NWD1 | c.3523A>C p.S1175R | Missense Mutation (SNP) | VAF 89/559 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- NWD2 | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- PCDHA6 | c.1781T>G p.V594G | Missense Mutation (SNP) | VAF 186/671 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCGF6 | c.674-32_680del p.X225_splice | Splice Site (DEL) | VAF 38/215 reads (18%) | called by mutect2, pindel
- PHTF1 | c.1779G>A p.W593* | Nonsense Mutation (SNP) | VAF 69/172 reads (40%) | called by muse, mutect2, varscan2
- PLD2 | c.2524T>G p.F842V | Missense Mutation (SNP) | VAF 142/409 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- RAB40AL | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 70/686 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- RAP2C | c.269T>C p.F90S | Missense Mutation (SNP) | VAF 130/448 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAVER2 | c.1664C>A p.T555K (on ENST00000294428 / NM_001366165.1; = p.T542K on NM_018211.4) | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- RFPL4A | c.341A>C p.D114A | Missense Mutation (SNP) | VAF 73/570 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RHOBTB2 | c.835T>G p.F279V | Missense Mutation (SNP) | VAF 146/800 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- RHOXF2 | c.176dup p.L60Vfs*46 | Frame Shift Ins (INS) | VAF 132/377 reads (35%) | called by mutect2, varscan2
- RIMKLB | c.269C>A p.T90N | Missense Mutation (SNP) | VAF 20/620 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.337); called by muse, mutect2
- RIPPLY3 | c.566C>G p.S189C | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RNF148 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); called by muse, mutect2
- RNPEPL1 | c.1015_1017del p.S339del | In Frame Del (DEL) | VAF 90/599 reads (15%) | called by pindel, varscan2
- RO60 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 126/248 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- SCN9A | c.2741T>C p.F914S (on ENST00000303354; = p.F903S on NM_002977.3) | Missense Mutation (SNP) | VAF 108/540 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC13A3 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 92/372 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- SLF1 | c.47A>C p.K16T | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2
- SPEN | c.9425C>T p.P3142L | Missense Mutation (SNP) | VAF 21/785 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2
- STAT3 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 16/434 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- STAT3 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2
- STRADA | c.550G>T p.D184Y (on ENST00000336174 / NM_001363786.1; = p.D147Y on NM_153335.6) | Missense Mutation (SNP) | VAF 199/344 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SUPT20H | c.1417G>A p.G473R (on ENST00000350612 / NM_001014286.3; = p.G474R on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/532 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); called by muse, mutect2
- TMPRSS7 | c.850C>G p.L284V (on ENST00000452346; = p.L158V on NM_001042575.2) | Missense Mutation (SNP) | VAF 72/390 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- TNRC6B | c.3148_3171dup p.L1050_S1057dup (on ENST00000454349 / NM_001162501.2; = p.L997_S1004dup on NM_015088.3) | In Frame Ins (INS) | VAF 41/132 reads (31%) | called by mutect2, varscan2
- TPRN | c.2_16del p.MAALG1_?5 | Translation Start Site (DEL) | VAF 248/627 reads (40%) | called by mutect2, varscan2
- TRPC5 | c.1951T>G p.F651V | Missense Mutation (SNP) | VAF 88/626 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTC7B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 167/466 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- UPK3A | c.525G>C p.L175F | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WASF3 | c.330A>C p.Q110H | Missense Mutation (SNP) | VAF 70/812 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2
- WDSUB1 | c.316T>C p.S106P | Missense Mutation (SNP) | VAF 90/507 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZFP42 | c.213T>G p.C71W | Missense Mutation (SNP) | VAF 80/573 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF282 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 129/912 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ZNF469 | c.9581G>A p.S3194N (on ENST00000437464; = p.S3222N on NM_001367624.2) | Missense Mutation (SNP) | VAF 197/1054 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ALG12 | c.1242C>T p.Y414= | Silent (SNP) | VAF 198/365 reads (54%) | catalogued as rs121907935, CM024735; called by muse, mutect2, varscan2
- AMN1 | c.516C>T p.V172= | Silent (SNP) | VAF 57/387 reads (15%) | catalogued as rs369471800; called by muse, mutect2, varscan2
- ARHGAP39 | c.1011C>A p.G337= | Silent (SNP) | VAF 246/869 reads (28%) | called by mutect2, varscan2
- ARL11 | c.33G>A p.A11= | Silent (SNP) | VAF 68/583 reads (12%) | catalogued as rs766455088, COSV56290961; called by muse, varscan2
- B3GNT7 | c.696C>T p.H232= | Silent (SNP) | VAF 121/659 reads (18%) | catalogued as rs372054406; called by muse, mutect2, varscan2
- BRCC3 | c.831G>A p.S277= | Silent (SNP) | VAF 105/452 reads (23%) | catalogued as rs781889631; called by muse, mutect2, varscan2
- BTN3A3 | c.789C>T p.L263= | Silent (SNP) | VAF 73/402 reads (18%) | catalogued as rs371725478; called by muse, mutect2, varscan2
- CDK12 | c.3921G>A p.Q1307= (on ENST00000447079 / NM_016507.4; = p.Q1298= on NM_015083.3) | Silent (SNP) | VAF 387/670 reads (58%) | called by muse, mutect2, varscan2
- CFAP74 | c.852G>A p.A284= | Silent (SNP) | VAF 106/508 reads (21%) | catalogued as rs376431848; called by muse, mutect2, varscan2
- CLSTN3 | c.1554G>A p.S518= | Silent (SNP) | VAF 119/396 reads (30%) | catalogued as rs756157048, COSV56934311; called by muse, mutect2, varscan2
- DNHD1 | c.4962G>C p.L1654= | Silent (SNP) | VAF 67/463 reads (14%) | called by muse, mutect2, varscan2
- DUSP9 | c.54G>A p.P18= | Silent (SNP) | VAF 211/1012 reads (21%) | called by muse, mutect2, varscan2
- FFAR1 | c.27C>T p.F9= | Silent (SNP) | VAF 245/534 reads (46%) | catalogued as rs1369977946; called by muse, mutect2, varscan2
- GABRB3 | c.15G>A p.A5= | Silent (SNP) | VAF 238/538 reads (44%) | called by muse, varscan2
- KMT2A | c.3456G>A p.S1152= | Silent (SNP) | VAF 210/474 reads (44%) | catalogued as rs782465215; called by muse, mutect2, varscan2
- LHX1 | c.192A>T p.A64= | Silent (SNP) | VAF 69/380 reads (18%) | catalogued as rs1487859281; called by muse, mutect2, varscan2
- LONRF3 | c.1383C>T p.D461= (on ENST00000371628 / NM_001031855.3; = p.D420= on NM_024778.5) | Silent (SNP) | VAF 116/566 reads (20%) | catalogued as COSV59150346; called by muse, mutect2, varscan2
- LRRC1 | c.516G>A p.Q172= | Silent (SNP) | VAF 27/217 reads (12%) | called by muse, mutect2, varscan2
- MNDA | c.610A>C p.R204= | Silent (SNP) | VAF 64/521 reads (12%) | catalogued as COSV63741058; called by muse, mutect2, varscan2
- MUSK | c.300G>C p.T100= | Silent (SNP) | VAF 44/286 reads (15%) | catalogued as rs180928221; called by muse, mutect2, varscan2
- MXRA5 | c.7128C>A p.P2376= | Silent (SNP) | VAF 235/906 reads (26%) | called by muse, mutect2, varscan2
- NR4A3 | c.927C>T p.C309= | Silent (SNP) | VAF 248/572 reads (43%) | catalogued as COSV100432421, COSV58248356; called by muse, mutect2, varscan2
- NRG2 | c.204G>A p.Q68= | Silent (SNP) | VAF 279/1630 reads (17%) | called by muse, mutect2, varscan2
- NRG3 | c.1851T>C p.S617= (on ENST00000404547 / NM_001370084.1; = p.S593= on NM_001010848.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 68/473 reads (14%) | catalogued as rs768186755, COSV64555595; called by muse, mutect2, varscan2
- OPRK1 | c.27C>T p.R9= | Silent (SNP) | VAF 255/875 reads (29%) | catalogued as rs777175554; called by muse, mutect2, varscan2
- OR5AR1 | c.438G>T p.L146= | Silent (SNP) | VAF 86/496 reads (17%) | catalogued as rs151139570; called by muse, mutect2, varscan2
- PCDHB3 | c.1488G>T p.P496= | Silent (SNP) | VAF 132/814 reads (16%) | called by muse, varscan2
- PRAMEF5 | c.1224A>G p.L408= | Silent (SNP) | VAF 91/394 reads (23%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2370C>G p.L790= | Silent (SNP) | VAF 177/306 reads (58%) | called by muse, mutect2, varscan2
- REELD1 | c.1164C>T p.S388= | Silent (SNP) | VAF 82/443 reads (19%) | called by muse, mutect2, varscan2
- SCN1A | c.1911G>A p.A637= | Silent (SNP) | VAF 369/817 reads (45%) | catalogued as rs192102141; ClinVar: likely benign; called by muse, mutect2, varscan2
- SKOR1 | c.1731G>A p.P577= | Silent (SNP) | VAF 21/807 reads (3%) | called by muse, mutect2
- SP140 | c.264G>T p.L88= | Silent (SNP) | VAF 31/413 reads (8%) | called by muse, mutect2
- SPTA1 | c.1530T>C p.S510= | Silent (SNP) | VAF 48/494 reads (10%) | called by muse, mutect2
- TENM4 | c.144C>T p.Y48= | Silent (SNP) | VAF 143/840 reads (17%) | catalogued as rs928730342, COSV53613360; called by muse, mutect2, varscan2
- TRPV5 | c.1644C>T p.D548= | Silent (SNP) | VAF 307/892 reads (34%) | catalogued as rs751587914; called by muse, varscan2
- TSEN54 | c.906C>T p.S302= | Silent (SNP) | VAF 468/802 reads (58%) | catalogued as rs774219646; called by muse, varscan2
- TSPAN10 | c.1101C>T p.P367= (on ENST00000574882 / NM_001290212.1; = p.P329= on NM_031945.4) | Silent (SNP) | VAF 404/948 reads (43%) | called by muse, mutect2
- UNC93A | c.1254G>C p.L418= | Silent (SNP) | VAF 78/432 reads (18%) | called by muse, mutect2, varscan2
- VWF | c.6615A>G p.P2205= | Silent (SNP) | VAF 70/454 reads (15%) | catalogued as rs1477319264; called by muse, mutect2, varscan2
- XRN1 | c.342G>A p.K114= | Silent (SNP) | VAF 88/227 reads (39%) | called by muse, mutect2, varscan2
- ZNF385D | c.868A>C p.R290= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as COSV55755947; called by muse, mutect2, varscan2
- ZNF831 | c.1125G>A p.G375= | Silent (SNP) | VAF 46/1026 reads (4%) | catalogued as COSV64039168; called by muse, mutect2
- ATP5MPL | c.124+534C>T | Intron (SNP) | VAF 22/517 reads (4%) | called by muse, mutect2
- CTBP2 | c.58+11431C>A | Intron (SNP) | VAF 97/652 reads (15%) | called by muse, mutect2, varscan2
- G6PD | c.771-97G>A | Intron (SNP) | VAF 92/692 reads (13%) | catalogued as rs1557230115; called by muse, mutect2, varscan2
- KCNQ1 | c.1394-17156dup | Intron (INS) | VAF 84/382 reads (22%) | called by mutect2, varscan2
- OSBPL6 | c.987+4568A>G | Intron (SNP) | VAF 89/611 reads (15%) | catalogued as rs749224530; called by muse, mutect2, varscan2
- PASK | c.3333+98G>C | Intron (SNP) | VAF 55/367 reads (15%) | catalogued as rs747707740; called by muse, mutect2, varscan2
